Somatic mutation profile of tumor specimen TCGA-J8-A4HW-01A (aliquot TCGA-J8-A4HW-01A-11D-A257-08) from TCGA case TCGA-J8-A4HW, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 59.1 years (21,587 days).
Specimen TCGA-J8-A4HW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6325aa02-72d8-4694-9c47-9acaee35f866.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A4HW-10A (Blood Derived Normal), aliquot TCGA-J8-A4HW-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeec7ef0-197a-4206-bd2b-2b0e664a53e5

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKMY1 | c.638A>T p.N213I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs199953888, COSV56037227; called by muse, mutect2, varscan2
- CFAP410 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950577318, COSV57395489; called by muse, mutect2
- CHST6 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100178710; called by muse, mutect2
- CYP19A1 | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV53060683; called by muse, mutect2, varscan2
- DNAH10 | c.5741G>T p.C1914F (on ENST00000409039; = p.C1853F on NM_207437.3) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766967012, COSV68996755; called by muse, mutect2, varscan2
- DNAH17 | c.1240T>A p.F414I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV67761261; called by muse, mutect2
- MED15 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV53031014; called by muse, mutect2, varscan2
- OR5L1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs112907233, COSV61735316, COSV99081997; called by muse, mutect2, varscan2
- RHEX | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs782607585; called by muse, mutect2
- TENM2 | c.4613C>T p.A1538V (on ENST00000518659 / NM_001122679.2; = p.A1299V on NM_001080428.3) | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370446142; called by muse, mutect2, varscan2
- PARP4 | c.142_157del p.I48Lfs*4 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- STAT4 | c.993G>A p.P331= | Silent (SNP) | VAF 13/175 reads (7%) | catalogued as rs559315611, COSV100636189, COSV61832397; called by muse, mutect2
- ADARB1 | chr21:45171625 G>A | 5'Flank (SNP) | VAF 6/28 reads (21%) | catalogued as COSV62345781; called by muse, mutect2, varscan2
